Somatic mutation profile of tumor specimen C3L-00412-01 (aliquot CPT0023310006) from CPTAC case C3L-00412, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 64.6 years (23,597 days).
Specimen C3L-00412-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e3b58bf-5a2f-4f35-a075-9aed76616062.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00412-31 (Blood Derived Normal), aliquot CPT0024540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/156c09f1-1969-49e4-b8a7-4c21306fcf46

The open-access MAF lists 127 somatic variants for this specimen: 79 protein-altering or splice-affecting, 32 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 32, Intron 8, 5'UTR 3, 3'UTR 3, Frame Shift Del 3, Nonsense Mutation 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 28/348 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ACACB | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58127889; called by muse, mutect2
- ANKRD12 | c.1358A>G p.D453G | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50822169; called by muse, mutect2
- ASNS | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs1210340204; called by muse, mutect2
- BANP | c.470G>T p.R157L (on ENST00000286122; = p.R126L on NM_017869.4) | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.985); catalogued as COSV99620623; called by muse, mutect2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 23/470 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2
- CSMD3 | c.2980A>T p.N994Y (on ENST00000297405 / NM_001363185.1; = p.N890Y on NM_052900.3) | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.808); catalogued as COSV52101845; called by muse, mutect2
- FAM120C | c.1417C>A p.H473N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.397); catalogued as rs1557130207; called by muse, mutect2, varscan2
- KPRP | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1436766592; called by muse, mutect2
- LGR5 | c.1900G>T p.G634W | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99877712; called by muse, mutect2
- MIA2 | c.1684G>C p.A562P | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV99696867; called by muse, mutect2
- MYH7 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 25/608 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV62521052; called by muse, mutect2
- NOBOX | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV56193767, COSV56193847; called by muse, mutect2
- NR0B1 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.964); catalogued as rs104894891, CM960020; called by muse, mutect2, varscan2
- PCDHGA4 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV99528127; called by muse, mutect2
- PCDHGC4 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs762408704, COSV99340032; called by muse, mutect2
- RTL5 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1334419545; called by muse, mutect2, varscan2
- SEMA5A | c.2420G>T p.R807L | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66787951; called by muse, mutect2
- SEMA6C | c.995G>T p.C332F | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59000518; called by muse, mutect2
- SIRPG | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.177); catalogued as COSV53806776; called by muse, mutect2
- SLC30A8 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69977046; called by muse, mutect2
- SMARCA4 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100758308, COSV60808184; called by muse, mutect2
- TGM6 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs575622127, COSV52478321, COSV99171659; called by muse, mutect2
- TRPC7 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs1160431714; called by muse, mutect2
- XIRP2 | c.1212G>T p.W404C (on ENST00000628543; = p.W579C on NM_152381.6) | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54723958; called by muse, mutect2
- ZNF135 | c.587G>T p.R196M (on ENST00000313434 / NM_001289401.2; = p.R208M on NM_003436.4) | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as rs1449744861, COSV100536963; called by muse, mutect2
- ZNF521 | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.052); catalogued as COSV64132976; called by muse, mutect2
- ZNF536 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV100835233, COSV62833010; called by muse, mutect2
- ACKR1 | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.938); called by muse, mutect2
- ADGRG4 | c.7295C>A p.T2432K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- BACH2 | c.1833G>T p.Q611H | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- BEND6 | c.209T>C p.L70S | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BPNT1 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2
- C8B | c.1579G>T p.V527F | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- CA9 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1C | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL11A1 | c.2983G>T p.E995* | Nonsense Mutation (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- COL4A1 | c.1762C>A p.P588T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL5A2 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CPNE5 | c.857T>A p.V286E | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- FAM187A | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FERMT1 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.78); called by muse, mutect2
- FLII | c.3317G>T p.G1106V | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GINM1 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.167); called by muse, mutect2
- GLYATL3 | c.4T>A p.L2M | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2
- GNAS | c.1367G>C p.G456A | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GOLGA3 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- H3C4 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.041); called by muse, mutect2
- HAVCR1 | c.1081T>C p.Y361H | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2
- IGHG4 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 18/524 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.335); called by muse, mutect2
- KEAP1 | c.182_206del p.K61Sfs*88 | Frame Shift Del (DEL) | VAF 8/126 reads (6%) | called by mutect2, pindel
- LHFPL1 | c.204del p.R69Afs*19 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel, varscan2
- LRRC17 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- MAGEA3 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- MAP3K3 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); called by muse, mutect2
- MIB2 | c.2918G>A p.R973H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.043); called by muse, mutect2
- MIB2 | c.2920A>T p.R974W | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEIL3 | c.1318A>G p.I440V | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- NRK | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- NUBPL | c.874T>C p.F292L | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- OR5D13 | c.467T>A p.V156E | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- OR6N1 | c.486G>T p.L162F | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.13481A>T p.H4494L | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDHA2 | c.851C>A p.T284N | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R3A | c.2738G>C p.S913T | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- PRPF6 | c.2344del p.E782Sfs*11 | Frame Shift Del (DEL) | VAF 14/169 reads (8%) | called by mutect2, pindel
- PRRT4 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.408); called by muse, mutect2
- RGS19 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SFRP1 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SH3TC2 | c.1575G>T p.W525C | Missense Mutation (SNP) | VAF 27/429 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC22A6 | c.1445A>T p.Y482F | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.106); called by muse, mutect2
- SMG5 | c.1950G>C p.M650I | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- TLR4 | c.1434G>C p.M478I (on ENST00000355622 / NM_138554.5; = p.M438I on NM_003266.4) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2
- TMEM47 | c.366A>C p.A122= | Splice Region (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2
- UNC80 | c.4822G>T p.G1608W | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- VIRMA | c.3817A>C p.S1273R | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.047); called by muse, mutect2
- ZNF609 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2
- ZNF626 | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2
- ZNF781 | c.215G>C p.C72S | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, mutect2
- ABCC8 | c.3843C>A p.G1281= | Silent (SNP) | VAF 26/388 reads (7%) | called by muse, mutect2
- ADAM21 | c.1272C>T p.S424= | Silent (SNP) | VAF 42/407 reads (10%) | catalogued as rs767652252; called by muse, mutect2, varscan2
- ASTL | c.1062C>A p.L354= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- BTBD11 | c.249C>T p.A83= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as rs1247619378; called by muse, mutect2
- CCDC88B | c.1122G>T p.L374= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- CECR2 | c.3813A>G p.T1271= (on ENST00000342247 / NM_001290047.2; = p.T1087= on NM_001290046.1) | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- CWH43 | c.1356C>T p.H452= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs752639867, COSV99893234; called by muse, mutect2
- EHD3 | c.30C>T p.R10= | Silent (SNP) | VAF 23/291 reads (8%) | catalogued as rs1196101111; called by muse, mutect2
- FSIP2 | c.20607C>A p.V6869= | Silent (SNP) | VAF 24/257 reads (9%) | called by muse, mutect2
- GANC | c.1035C>T p.F345= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV99040624; called by muse, varscan2
- GORASP2 | c.1302A>T p.P434= | Silent (SNP) | VAF 22/347 reads (6%) | called by muse, mutect2
- GPD2 | c.1002G>T p.A334= | Silent (SNP) | VAF 19/295 reads (6%) | called by muse, mutect2
- GPRIN2 | c.954A>T p.S318= | Silent (SNP) | VAF 13/316 reads (4%) | called by muse, mutect2
- HFM1 | c.618T>C p.Y206= | Silent (SNP) | VAF 17/192 reads (9%) | called by muse, mutect2
- ITIH5 | c.444C>A p.P148= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV56900398, COSV56917083; called by muse, mutect2
- LINGO1 | c.1014C>T p.R338= | Silent (SNP) | VAF 31/278 reads (11%) | catalogued as rs770463478, COSV62438452; called by muse, mutect2, varscan2
- MC3R | c.198C>T p.N66= | Silent (SNP) | VAF 12/294 reads (4%) | catalogued as rs961326205, COSV54763540; called by muse, mutect2
- OR52J3 | c.72C>T p.D24= | Silent (SNP) | VAF 27/240 reads (11%) | catalogued as rs1416834994; called by muse, mutect2, varscan2
- OR5J2 | c.162A>G p.K54= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV56622579; called by muse, mutect2
- OR8G5 | c.150G>T p.G50= | Silent (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
- PCDH15 | c.2157T>A p.P719= | Silent (SNP) | VAF 26/290 reads (9%) | called by muse, mutect2
- PCNX1 | c.1431C>T p.H477= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs1394446612; called by muse, mutect2
- PIK3R6 | c.1416G>C p.P472= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- PKHD1L1 | c.5466T>A p.A1822= | Silent (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- POTEB3 | c.117C>A p.G39= | Silent (SNP) | VAF 23/690 reads (3%) | called by muse, mutect2
- PRR32 | c.651C>A p.G217= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- RBM4B | c.615C>T p.Y205= | Silent (SNP) | VAF 24/343 reads (7%) | catalogued as rs1418920680; called by muse, mutect2
- RYR2 | c.7011A>G p.G2337= | Silent (SNP) | VAF 10/210 reads (5%) | catalogued as COSV63677530; called by muse, mutect2
- TCERG1L | c.1110C>A p.P370= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- TICRR | c.165G>A p.A55= | Silent (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- TRPM4 | c.876C>G p.T292= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2
- TTN | c.15399C>A p.P5133= (on ENST00000591111; = p.P4206= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- C5orf17 | n.196G>T | RNA (SNP) | VAF 10/55 reads (18%) | called by muse, varscan2
- CCDC178 | c.2389-8625T>A | Intron (SNP) | VAF 13/173 reads (8%) | called by muse, mutect2
- CEP164 | c.393+3430G>T | Intron (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- GRK3 | c.-23C>T | 5'UTR (SNP) | VAF 14/176 reads (8%) | catalogued as rs1370651239; called by muse, mutect2
- GRK3 | c.-22G>T | 5'UTR (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- GRM1 | c.2661-7312A>T | Intron (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- HADH | c.133-5091G>A | Intron (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- HEPACAM2 | c.*64T>A | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- MBD1 | c.*53G>T | 3'UTR (SNP) | VAF 17/262 reads (6%) | called by muse, mutect2
- NAV3 | c.6519-170T>A | Intron (SNP) | VAF 6/143 reads (4%) | called by muse, mutect2
- RPL26P30 | n.971A>G | RNA (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- UGGT2 | c.931+390T>C | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- UMODL1 | c.1899+19G>T | Intron (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- UQCRB | c.*2700C>T | 3'UTR (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
- ZFP57 | c.-20G>T | 5'UTR (SNP) | VAF 22/328 reads (7%) | called by muse, mutect2
- ZNF720 | c.361+607C>T | Intron (SNP) | VAF 11/91 reads (12%) | catalogued as rs1393412417; called by muse, mutect2
